Gene-level copy-number profile of tumor specimen TCGA-44-7662-01A from TCGA case TCGA-44-7662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.7 years (22,543 days).
Specimen TCGA-44-7662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f332d2d2-9688-4479-b6d3-b16f5a9a47c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-7662-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99414751-afb2-4c58-8f84-e8ddd15a788a

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 28,837; copy number 2: 21,614; copy number 3: 7,267; copy number 4: 1,844; copy number 5: 26; copy number 6: 53; copy number 7: 24; copy number 10: 27; copy number 11: 3; copy number 12: 37; copy number 13: 21; copy number 15: 9; copy number 18: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-7662-01A-11D-2062-01): tumor purity 0.33, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–51,055,459, 12 genes: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 9,323 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,636,877–77,943,895, 28 genes, copy number 3: AC104458.1, TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3–4 (broad region; genes not listed).
- chr5:58,198–32,110,932, 479 genes, copy number 3–7 (within-gene range 1–7) (broad region; genes not listed).
- chr5:32,354,350–45,895,970, 221 genes, copy number 3–15 (broad region; genes not listed).
- chr6:71,028,582–79,874,610, 128 genes, copy number 4 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 3 (broad region; genes not listed).
- chr7:115,789,729–119,179,149, 60 genes, copy number 4–18: AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1.
- chr9:117,180,628–119,524,125, 18 genes, copy number 3: RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1.
- chr10:110,567,695–111,989,909, 21 genes, copy number 13 (within-gene range 7–13): SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1, BTBD7P2, AC021035.1, RPS6P15, AL136119.1.
- chr10:112,395,813–114,046,904, 27 genes, copy number 3–7 (within-gene range 1–7): AL157786.1, ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1.
- chr11:45,929,319–135,075,908, 2,336 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr14:21,918,188–22,499,749, 74 genes, copy number 3 (broad region; genes not listed).
- chr16:46,469,341–51,038,764, 124 genes, copy number 3 (broad region; genes not listed).
- chr17:13,299,184–13,306,771, 1 gene, copy number 3: LINC02093.
- chr17:26,981,694–83,095,122, 2,120 genes, copy number 3 (broad region; genes not listed).
- chr18:28,638,714–28,824,826, 3 genes, copy number 3: AC090365.1, ARIH2P1, AC023932.1.

Autosomal genes at a single copy (total copy number 1): 26,450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
